MMRF case MMRF_1212 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c07b285d-2532-4d71-9372-2da12f7a5a3f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 78 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 78.4 years (28,625 days); ISS stage: III; Days to last known disease status: 1,252 days (3.4 years); Days to last follow up: 1,252 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 233 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 148 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 148 days.
   Treatment given: Therapeutic agents: Prednisone + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 233 days; Days to treatment end: 657 days (1.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 2): M Protein 3.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 823 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.067 mg/dL; Immunoglobulin G 3.11 g/L; Immunoglobulin A 45.7 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 6.26 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.53 mmol/L; Albumin 36 g/L; Total Protein 8.8 g/dL; Glucose 5.01 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 90 (ECOG 0): M Protein 1.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 576 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.047 mg/dL; Immunoglobulin G 2.24 g/L; Immunoglobulin A 14.4 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 6.99 mmol/L.
- Day 181 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 354 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.074 mg/dL; Immunoglobulin G 1.73 g/L; Immunoglobulin A 9.96 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 127 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 243 (ECOG 1): M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 81.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.063 mg/dL; Immunoglobulin G 2.06 g/L; Immunoglobulin A 4.87 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 5.56 mmol/L.
- Day 320 (ECOG 0): M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 79.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.589 mg/dL; Immunoglobulin G 2.31 g/L; Immunoglobulin A 4.79 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 4.38 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 29 g/L; Total Protein 6.3 g/dL; Glucose 4.95 mmol/L.
- Day 496 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.607 mg/dL; Immunoglobulin G 3.24 g/L; Immunoglobulin A 2.86 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 5.39 mmol/L.
- Day 770: Serum Free Immunoglobulin Light Chain, Kappa 4.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.408 mg/dL; Hemoglobin 7.69 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Glucose 4.24 mmol/L.
- Day 882: Serum Free Immunoglobulin Light Chain, Kappa 48.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 7.35 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.96 ×10⁹/L; Platelets 128 ×10⁹/L; Albumin 39 g/L; Total Protein 6.1 g/dL.
- Day 947: Serum Free Immunoglobulin Light Chain, Kappa 2.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 4.23 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.95 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.21 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 5 g/dL; Glucose 7.04 mmol/L.
- Day 1,252: M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16 mg/dL; Immunoglobulin G 8.83 g/L; Immunoglobulin M 0.59 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.55 mmol/L; Albumin 35 g/L; Total Protein 7.6 g/dL; Glucose 3.47 mmol/L.

Other clinical attributes
- Day -1: Weight: 71 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1212_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1212_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
